Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4JZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4JZ-01A (Primary Tumor).

[page 1 of 2]
Sex: F

Physician: _____

Accession: _____

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) RIGHT MID JUGULAR LYMPH NODE:

One lymph node, negative for tumor (0/1).

(B) RIGHT SUPERIOR PARATHYROID LYMPH NODE:

One lymph node, negative for tumor (0/1).

(C) RIGHT MEDIASTINAL CONTENTS:

Three lymph nodes, negative for tumor (0/3).

(D) DELPHIAN NODE:

Thyroid parenchyma and fibroconnective tissue, negative for tumor and lymph node.

(E) PORTION OF LEFT SUPERIOR PARATHYROID GLAND:

Minute fragments of parathyroid tissue, no tumor present.

(F) LEFT NECK CONTENTS:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF TWELVE LYMPH NODES (1/12) confined to node.

(G) RIGHT PARATRACHEAL AND MEDIASTINAL CONTENTS:

METASTATIC PAPILLARY THYROID CARCINOMA IN FIVE OF SIXTEEN LYMPH NODES (5/6) confined to node.

(H) TOTAL THYROIDECTOMY AND LEFT PARATRACHEAL MEDIASTINAL CONTENTS:

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: isthmus

Multi-focal: No

Size = 2.0 cm

Extrathyroidal extension: Present, extending into fibroadipose tissue

Lymphovascular invasion: Absent

Resection Margins: Negative

Background Thyroid: Chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Lymph nodes: No tumor present in 2 lymph nodes

Parathyroid tissue present (H8)

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

ju
10/4/12

GROSS DESCRIPTION

[page 2 of 2]
DOB:
Physician:

Sex: F

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

- (A) RIGHT MID JUGULAR LYMPH NODE – A single possible lymph node measuring 0.7 cm in its greatest dimension. Entirely submitted in cassette A.
- (B) RIGHT SUPERIOR PARATHYROID LYMPH NODE – A single fragment of fibrofatty tissue measuring 0.8 cm in its greatest dimension. Entirely submitted in cassette B.
- (C) RIGHT MEDIASTINAL CONTENTS – Three fragments of fibrofatty tissue measuring in aggregate 1 x 1 x 0.8 cm. Entirely submitted in cassette C.
- (D) DELPHIAN NODE – A single possible lymph node with attached fatty tissue measuring 1 x 0.8 x 0.4 cm. Entirely submitted in D.
- (E) PORTION OF LEFT SUPERIOR PARATHYROID GLAND – A (0.2 x 0.1 x 0.1 cm) pink-tan soft tissue fragment. Entirely submitted for frozen section diagnosis in E.

*FS/DX: PARATHYROID TISSUE PRESENT.

- (F) LEFT NECK CONTENTS – A single fragment of fibrofatty tissue measuring 6.5 x 3 x 1 cm. Dissection reveals multiple possible lymph nodes ranging from 0.5 up to 0.7 cm in their greatest dimension. Possible lymph nodes are entirely submitted.

SECTION CODE: F1, five possible lymph nodes; F2, five possible lymph nodes; F3, five possible nodes.

- (G) RIGHT PARATRACHEAL AND MEDIASTINAL CONTENTS – A single fragment of fibrofatty tissue measuring 5.5 x 2 x 1.0 cm. Dissection reveals multiple possible lymph nodes, ranging from 0.4 up to 1.1 cm in their greatest dimension. Possible lymph nodes are entirely submitted.

SECTION CODE: G1, six possible lymph nodes; G2, five possible lymph nodes; G3, one sectioned possible lymph node; G4, one sectioned possible lymph node; G5, one lymph node; G6, one lymph node; G7, one lymph node.

- (H) TOTAL THYROIDECTOMY AND LEFT PARATRACHEAL MEDIASTINAL CONTENTS – A total thyroidectomy with anterior strap muscles covering the anterior portion of specimen (6 x 6 x 2 cm). The thyroid shows nodular changes suggestive of chronic lymphocytic thyroiditis. The right lobe has diffuse changes of thyroiditis. Within the isthmus, a superior nodule is firm, tan, extending and focally adherent to the skeletal muscle and extending into the left thyroid lobe (2 x 1.6 x 1.5 cm). The left lobe also shows nodular changes, suggestive of thyroiditis with a slightly firmer and inferior nodule (1.5 x 1 x 0.5 cm). Within the surrounding fibroadipose tissue, possible lymph nodes are identified.

SECTION CODE: H1, H2, sections of right thyroid superior to inferior; H3, H4, tumor at isthmus with attached soft tissue; H5, H6, superior left thyroid and adjacent isthmus nodule; H7, inferior left thyroid; H8, a separate nodule submitted with specimen, bisected; H9, additional possible lymph nodes; H10, additional adipose tissue.

CLINICAL HISTORY

Thyroid lesion.

SNOMED CODES

T-B6000, T-C4200, M-80503, M-B0630

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 2 of 2	
File under: Pathology		Criteria	Yes No

Source: NCI Genomic Data Commons file dc5c0661-9706-47a5-a70d-709028bde0f1 (TCGA-EL-A4JZ.E8887291-5C5F-46B8-BFA9-A959B8510345.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).